Somatic mutation profile of tumor specimen TCGA-GV-A3JX-01A (aliquot TCGA-GV-A3JX-01A-11D-A20D-08) from TCGA case TCGA-GV-A3JX, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 59.9 years (21,888 days).
Specimen TCGA-GV-A3JX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c70d450e-7dd4-4c2f-9589-b80d4167625b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GV-A3JX-10A (Blood Derived Normal), aliquot TCGA-GV-A3JX-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/234daef4-d4cf-475d-b355-9ea15437aac4

The open-access MAF lists 297 somatic variants for this specimen: 228 protein-altering or splice-affecting, 56 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 203, Silent 56, Nonsense Mutation 15, Intron 6, Splice Site 3, Frame Shift Ins 3, RNA 2, Frame Shift Del 2, 5'Flank 2, Splice Region 2, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 37/94 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 75/88 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.1159C>G p.L387V | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.26); catalogued as COSV53978967; called by muse, mutect2, varscan2
- ABHD8 | c.1023G>T p.M341I | Missense Mutation (SNP) | VAF 20/211 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as COSV56045600; called by muse, mutect2, varscan2
- ABTB2 | c.2600C>G p.S867C | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54392233; called by muse, mutect2, varscan2
- ACAD11 | c.977G>C p.R326T | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1271874230, COSV53899143; called by muse, mutect2
- ACSL6 | c.1304C>T p.A435V (on ENST00000379240; = p.A460V on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV57301891; called by muse, mutect2, varscan2
- ACSM2B | c.1538C>A p.S513* | Nonsense Mutation (SNP) | VAF 77/90 reads (86%) | catalogued as CM035887, COSV61659248; called by muse, mutect2, varscan2
- ACTB | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV59316980, COSV59319876; called by muse, mutect2
- ADAR | c.3667C>G p.L1223V | Missense Mutation (SNP) | VAF 82/300 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV52718155; called by muse, mutect2, varscan2
- ADAR | c.1639C>T p.P547S | Missense Mutation (SNP) | VAF 15/230 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52718171; called by muse, mutect2
- AGO3 | c.2299C>T p.H767Y | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV55795216; called by muse, mutect2, varscan2
- AGO3 | c.2449C>T p.H817Y | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.679); catalogued as COSV55795224; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.7085G>A p.R2362Q | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs780806092, COSV51853254; called by muse, mutect2, varscan2
- ANKZF1 | c.1954C>T p.L652F | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1256478131, COSV55477693; called by muse, mutect2, varscan2
- ARMC4 | c.233C>G p.T78R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV53466945; called by muse, mutect2, varscan2
- ATP9B | c.1823G>C p.R608T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV56956426; called by muse, mutect2, varscan2
- BDH2 | c.621G>T p.K207N | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV56479039; called by muse, mutect2
- BDP1 | c.5124G>C p.Q1708H | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as COSV62432781; called by muse, mutect2, varscan2
- BDP1 | c.5751G>C p.Q1917H | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.363); catalogued as COSV62432786; called by muse, mutect2, varscan2
- BLZF1 | c.174G>C p.E58D | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); catalogued as COSV61394303; called by muse, mutect2, varscan2
- BLZF1 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61394314; called by muse, mutect2, varscan2
- C12orf4 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.773); catalogued as COSV54208287; called by muse, mutect2
- CAMK4 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1386520704, COSV56677300; called by muse, mutect2, varscan2
- CARD8 | c.497G>A p.G166E (on ENST00000651546 / NM_001184900.3; = p.G116E on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/129 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV62874394; called by muse, mutect2, varscan2
- CAVIN2 | c.711G>C p.K237N | Missense Mutation (SNP) | VAF 19/276 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV58424880; called by muse, mutect2
- CBLB | c.2776G>A p.E926K | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.197); catalogued as COSV51426744, COSV51431714; called by muse, mutect2
- CCDC88A | c.1591C>G p.L531V | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55066246; called by muse, mutect2, varscan2
- CCSER1 | c.763C>G p.Q255E | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.318); catalogued as COSV61449218; called by muse, mutect2, varscan2
- CD93 | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 22/370 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV55667064, COSV99849516; called by muse, mutect2
- CDH9 | c.182T>C p.F61S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV50344755; called by muse, mutect2, varscan2
- CEP126 | c.3322G>C p.D1108H | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV54828077; called by muse, mutect2
- CFH | c.266G>C p.G89A | Missense Mutation (SNP) | VAF 17/288 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); catalogued as COSV62778268; called by muse, mutect2
- CHRD | c.2171C>T p.P724L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.788); catalogued as rs781476129; called by muse, mutect2, varscan2
- CLCA2 | c.2636C>T p.S879F | Missense Mutation (SNP) | VAF 34/392 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV65288026; called by muse, mutect2
- CPN2 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as rs775357382, COSV60471098; called by muse, mutect2, varscan2
- CREBBP | c.2666C>G p.S889* | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as COSV99269904, COSV99272743; called by muse, mutect2, varscan2
- CSMD2 | c.7571C>T p.P2524L | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53935221; called by muse, mutect2, varscan2
- CUL1 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.31); catalogued as COSV57388811; called by muse, mutect2, varscan2
- CYP27A1 | c.1352G>C p.R451T | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV51467954, COSV99298828; called by muse, mutect2
- DAPK1 | c.2090G>A p.G697E | Missense Mutation (SNP) | VAF 87/173 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as COSV63788317; called by muse, mutect2, varscan2
- DDC | c.1355C>T p.S452F | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as COSV63566416; called by muse, mutect2, varscan2
- DGKG | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 69/192 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as COSV53968742; called by muse, mutect2, varscan2
- DHRS7B | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.871); catalogued as COSV60888259; called by muse, mutect2, varscan2
- DLAT | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs200147835, COSV54769022, COSV54772061; called by muse, varscan2
- DMRT1 | c.32C>G p.S11C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.52); catalogued as COSV66522879; called by muse, mutect2, varscan2
- DNAAF3 | c.136G>A p.E46K (on ENST00000524407 / NM_001256715.2; = p.E93K on NM_178837.4) | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); catalogued as COSV66993714; called by muse, mutect2, varscan2
- DNAH11 | c.12898C>T p.R4300C | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs796872314, COSV60964637; called by muse, mutect2, varscan2
- DOCK8 | c.5038G>C p.E1680Q | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV66622072; called by muse, mutect2, varscan2
- DPYS | c.1154T>G p.I385S | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1244046163, COSV59827165; called by muse, mutect2, varscan2
- DSC3 | c.1463C>T p.S488L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV64574111; called by muse, mutect2, varscan2
- DSG4 | c.877A>G p.I293V | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as COSV57394525; called by muse, mutect2, varscan2
- EIF4A3 | c.891G>A p.M297I | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV53921259; called by muse, mutect2, varscan2
- ENOX2 | c.1180G>C p.E394Q (on ENST00000338144 / NM_001382520.1; = p.E365Q on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/58 reads (93%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as COSV57655281; called by muse, mutect2, varscan2
- EP300 | c.4578G>C p.E1526D | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV54338689; called by muse, mutect2, varscan2
- EPHA3 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 131/300 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV60708883, COSV60724242; called by muse, mutect2, varscan2
- F8 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM031979, CM080250, COSV64276285; called by muse, mutect2, varscan2
- FAM83G | c.2032G>C p.D678H | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.167); catalogued as COSV58760184; called by mutect2, varscan2
- FAT3 | c.2560G>A p.E854K | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.605); catalogued as COSV53144630; called by muse, mutect2, varscan2
- FCAR | c.658C>A p.H220N | Missense Mutation (SNP) | VAF 74/878 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100629168, COSV62030803; called by muse, mutect2
- FLT3 | c.2146G>C p.E716Q | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV54049166, COSV54061682; called by muse, mutect2
- FMNL3 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 11/204 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as rs776117483, COSV53305012; called by muse, mutect2
- FRY | c.3010G>C p.E1004Q | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV66574421; called by muse, mutect2
- GALNTL5 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753967781, COSV67180673; called by muse, mutect2, varscan2
- GOLGA2 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766471494, COSV68597312; called by muse, mutect2
- GP2 | c.931G>C p.D311H (on ENST00000381362 / NM_001007240.3; = p.D308H on NM_001502.4) | Missense Mutation (SNP) | VAF 134/162 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56895359; called by muse, mutect2, varscan2
- GSTZ1 | c.567C>G p.I189M | Missense Mutation (SNP) | VAF 61/118 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53623995; called by muse, mutect2, varscan2
- GTPBP1 | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 48/67 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53286404; called by muse, mutect2, varscan2
- HCAR1 | c.632G>C p.R211T | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV63676205; called by muse, mutect2, varscan2
- HCAR1 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as rs370201170, COSV63676211; called by muse, mutect2, varscan2
- HECTD1 | c.1693G>A p.D565N | Missense Mutation (SNP) | VAF 84/187 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV67947933; called by muse, mutect2, varscan2
- HERC6 | c.2719G>C p.D907H | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52032338; called by muse, mutect2, varscan2
- HNRNPR | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 99/213 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); catalogued as COSV56423041; called by muse, mutect2, varscan2
- HRNR | c.3245C>T p.T1082I | Missense Mutation (SNP) | VAF 264/988 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.208); catalogued as rs748398456, COSV64257556, COSV64260491; called by muse, mutect2, varscan2
- HSPD1 | c.864G>C p.L288F | Missense Mutation (SNP) | VAF 17/257 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV61445277; called by muse, mutect2
- HUWE1 | c.4130G>C p.R1377T | Missense Mutation (SNP) | VAF 123/136 reads (90%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV53355766; called by muse, mutect2, varscan2
- INTS3 | c.2920G>A p.E974K | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV55162882, COSV55164753; called by muse, mutect2, varscan2
- IPPK | c.184G>A p.V62I | Missense Mutation (SNP) | VAF 67/163 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.04); catalogued as COSV55334965; called by muse, mutect2, varscan2
- KALRN | c.1345G>T p.D449Y | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV53773174; called by muse, mutect2, varscan2
- KCNB2 | c.1456C>G p.H486D | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV73051541; called by muse, mutect2
- KCTD19 | c.2721G>C p.Q907H | Missense Mutation (SNP) | VAF 74/94 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV58573898; called by muse, mutect2, varscan2
- KIF26A | c.3680G>A p.R1227H | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs779208185, COSV59468508; called by muse, mutect2, varscan2
- KIRREL1 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753693433, COSV63289429; called by muse, mutect2, varscan2
- KLRC4 | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as COSV58672103; called by muse, mutect2
- KMT2C | c.1450C>A p.H484N | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.15); catalogued as COSV51470347; called by muse, mutect2, varscan2
- KRT33A | c.1001G>T p.R334L | Missense Mutation (SNP) | VAF 85/206 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50365566, COSV50370191; called by mutect2, varscan2
- KRT34 | c.478C>G p.L160V | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV67449639, COSV67450278; called by muse, mutect2, varscan2
- KRT79 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.102); catalogued as rs772094718, COSV100398497, COSV57941231; called by muse, mutect2, varscan2
- KRTAP5-7 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 158/392 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.071); catalogued as COSV68325456; called by muse, varscan2
- KTN1 | c.3774G>A p.L1258= (on ENST00000395314 / NM_001271014.2; = p.L1201= on NM_004986.4) | Splice Region (SNP) | VAF 23/59 reads (39%) | catalogued as COSV58540715; called by muse, mutect2, varscan2
- LAD1 | c.1503G>C p.E501D | Missense Mutation (SNP) | VAF 131/202 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV66212934; called by muse, mutect2, varscan2
- LAMA2 | c.6749G>A p.G2250E | Missense Mutation (SNP) | VAF 118/148 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs936469552, COSV70351976; called by muse, mutect2, varscan2
- LAMA5 | c.2727G>A p.M909I | Missense Mutation (SNP) | VAF 40/63 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53365558; called by muse, mutect2, varscan2
- LIMA1 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV57966945; called by muse, mutect2, varscan2
- LRP12 | c.1184G>A p.C395Y | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52631591; called by muse, mutect2
- LYST | c.11378C>G p.S3793C | Missense Mutation (SNP) | VAF 12/350 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV67710504, COSV67714860; called by muse, mutect2
- MALSU1 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 128/272 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.235); catalogued as rs1463581260, COSV54978998; called by muse, mutect2, varscan2
- MAN2A1 | c.45C>G p.F15L | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV54855167; called by muse, mutect2, varscan2
- MAP9 | c.697C>G p.L233V | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.045); catalogued as COSV60905566; called by muse, varscan2
- MAPK7 | c.1813C>T p.P605S | Missense Mutation (SNP) | VAF 15/15 reads (100%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as rs1384793471, COSV55191144; called by muse, mutect2, varscan2
- MAPT | c.1531C>A p.P511T (on ENST00000262410 / NM_001377265.1; = p.P436T on NM_016835.4) | Missense Mutation (SNP) | VAF 130/303 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.378); catalogued as COSV52243677; called by muse, varscan2
- MAPT | c.1532C>T p.P511L (on ENST00000262410 / NM_001377265.1; = p.P436L on NM_016835.4) | Missense Mutation (SNP) | VAF 129/304 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.714); catalogued as COSV52243703; called by muse, varscan2
- MAPT | c.1591G>A p.E531K (on ENST00000262410 / NM_001377265.1; = p.E456K on NM_016835.4) | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV52237895; called by muse, varscan2
- MARCHF10 | c.1462G>T p.D488Y | Missense Mutation (SNP) | VAF 15/171 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV60889225; called by muse, mutect2
- MC4R | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 48/76 reads (63%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV55352745; called by muse, mutect2, varscan2
- MED1 | c.606G>C p.K202N | Missense Mutation (SNP) | VAF 102/245 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.281); catalogued as COSV56124560, COSV56127098; called by muse, mutect2, varscan2
- MFSD6 | c.1990C>G p.R664G | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV55624008, COSV99855018; called by muse, mutect2
- MID1 | c.1303G>C p.D435H | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV58196981, COSV58200895; called by muse, mutect2
- MKI67 | c.6000G>C p.K2000N | Missense Mutation (SNP) | VAF 189/239 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs753450662, COSV64075597; called by muse, mutect2, varscan2
- MMAB | c.343C>T p.Q115* | Nonsense Mutation (SNP) | VAF 27/328 reads (8%) | catalogued as COSV99904650; called by muse, mutect2
- MMP16 | c.568T>A p.S190T | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV54177034; called by muse, mutect2, varscan2
- MRGPRX3 | c.264C>G p.I88M | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.542); catalogued as COSV66934385; called by muse, mutect2, varscan2
- MYH9 | c.3007G>A p.E1003K | Missense Mutation (SNP) | VAF 71/92 reads (77%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.824); catalogued as COSV53389942; called by muse, varscan2
- MYH9 | c.2573G>C p.R858T | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV53381788; called by muse, mutect2, varscan2
- MYH9 | c.2248G>C p.D750H | Missense Mutation (SNP) | VAF 42/52 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53389956; called by muse, mutect2, varscan2
- MYLK2 | c.898T>A p.C300S | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.18); catalogued as COSV65659524; called by muse, mutect2, varscan2
- MYO1C | c.3063C>T p.G1021= (on ENST00000648651 / NM_001080779.2; = p.G986= on NM_033375.5) | Splice Region (SNP) | VAF 11/88 reads (13%) | catalogued as COSV63000045; called by muse, mutect2, varscan2
- NAA25 | c.797A>G p.Y266C | Missense Mutation (SNP) | VAF 88/215 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55706529; called by muse, mutect2, varscan2
- NAAA | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV54431793; called by muse, mutect2, varscan2
- NIBAN2 | c.620C>G p.P207R | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.184); catalogued as COSV64823842, COSV64824949; called by muse, mutect2, varscan2
- NOP58 | c.1292C>G p.S431C | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV51897660; called by muse, mutect2, varscan2
- NSMAF | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 36/77 reads (47%) | catalogued as COSV50697649; called by muse, varscan2
- NUSAP1 | c.707G>C p.R236T | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); catalogued as COSV52972159; called by muse, mutect2, varscan2
- OR10J1 | c.77C>T p.T26I | Missense Mutation (SNP) | VAF 210/359 reads (58%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as COSV71129231; called by muse, mutect2, varscan2
- OR13C2 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as COSV73377725; called by muse, mutect2, varscan2
- OR2D3 | c.239G>C p.R80T | Missense Mutation (SNP) | VAF 66/143 reads (46%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV58573478, COSV58574064; called by muse, mutect2
- OR51F1 | c.898A>G p.I300V | Missense Mutation (SNP) | VAF 67/147 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.16); catalogued as COSV58580229; called by muse, mutect2, varscan2
- OR6Y1 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 65/170 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56930296; called by muse, mutect2, varscan2
- OR8B2 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 43/251 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); catalogued as rs772030593, COSV100899262, COSV66665073; called by muse, mutect2
- PAIP1 | c.1387G>C p.E463Q | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV100166595; called by muse, mutect2
- PANK3 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 32/252 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.065); catalogued as COSV53324285; called by muse, mutect2, varscan2
- PCDH11X | c.1895A>G p.D632G | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100011529; called by muse, mutect2, varscan2
- PCDH19 | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 40/45 reads (89%) | SIFT tolerated (0.74); PolyPhen benign (0.023); catalogued as COSV55267388; called by muse, mutect2, varscan2
- PCDH8 | c.1927G>T p.E643* | Nonsense Mutation (SNP) | VAF 14/28 reads (50%) | catalogued as COSV100131603, COSV58810863; called by muse, mutect2, varscan2
- PCDH8 | c.1806G>C p.Q602H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV58814136; called by muse, mutect2, varscan2
- PCDHB7 | c.901C>T p.L301F | Missense Mutation (SNP) | VAF 88/102 reads (86%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV50792895; called by muse, mutect2, varscan2
- PDCD11 | c.3421G>A p.E1141K | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.036); catalogued as COSV63934604; called by muse, mutect2, varscan2
- PDCD1LG2 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs201840318, COSV67205081; called by muse, mutect2, varscan2
- PDE1C | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs199785741, COSV58507431, COSV58519205, COSV58520797; called by muse, mutect2
- PI15 | c.686G>T p.C229F | Missense Mutation (SNP) | VAF 87/203 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52641467; called by muse, varscan2
- PIAS4 | c.711G>C p.K237N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53680144; called by muse, mutect2, varscan2
- PIGL | c.311C>G p.S104C | Missense Mutation (SNP) | VAF 91/102 reads (89%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV56686614; called by muse, varscan2
- PIK3C2G | c.2182G>A p.E728K (on ENST00000676171; = p.E687K on NM_004570.5) | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.115); catalogued as COSV56820385; called by muse, mutect2, varscan2
- POLR1G | c.1287G>C p.E429D | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV50004788, COSV50005033; called by muse, mutect2, varscan2
- PRDM2 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.813); catalogued as rs750242269; called by muse, mutect2
- PRKACB | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 20/267 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.988); catalogued as COSV65760305; called by muse, mutect2
- PRKDC | c.7137G>T p.M2379I | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV58058252, COSV58058402; called by muse, mutect2
- PRRC2A | c.4933G>C p.E1645Q | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV52993078; called by muse, mutect2, varscan2
- PSEN1 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.033); catalogued as COSV56195663; called by muse, mutect2
- PTBP2 | c.1493G>C p.R498T (on ENST00000426398 / NM_001300986.2; = p.X489_splice on NM_021190.4) | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV64624527; called by muse, mutect2
- PTPRD | c.2147G>A p.R716H | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs758558790, COSV61931118, COSV61932074; called by muse, varscan2
- QPCTL | c.1021C>G p.L341V | Missense Mutation (SNP) | VAF 99/243 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.1); catalogued as COSV50004326; called by muse, mutect2, varscan2
- RAB11FIP4 | c.1787C>T p.S596L | Missense Mutation (SNP) | VAF 77/148 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs778767376, COSV57930340; called by muse, mutect2, varscan2
- RB1 | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 79/97 reads (81%) | catalogued as CD143491, COSV57297033; called by muse, mutect2, varscan2
- REV3L | c.2291C>A p.A764D | Missense Mutation (SNP) | VAF 102/120 reads (85%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as COSV62621266; called by muse, varscan2
- REV3L | c.2162C>G p.S721C | Missense Mutation (SNP) | VAF 52/60 reads (87%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.818); catalogued as rs748286892, COSV62621278; called by muse, varscan2
- RPL24 | c.167G>C p.R56T | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67530075, COSV67530168; called by muse, mutect2, varscan2
- SALL2 | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58104692; called by muse, mutect2, varscan2
- SCN9A | c.695A>C p.K232T | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57617191; called by muse, mutect2, varscan2
- SEMA3D | c.862-1G>C p.X288_splice | Splice Site (SNP) | VAF 97/202 reads (48%) | catalogued as COSV52398685; called by muse, mutect2, varscan2
- SERPINA9 | c.119C>G p.P40R | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV54076591; called by muse, varscan2
- SHC4 | c.57C>A p.F19L | Missense Mutation (SNP) | VAF 101/133 reads (76%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs761322567, COSV60113227, COSV60114549; called by muse, mutect2, varscan2
- SHROOM2 | c.1373C>T p.P458L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV66608878; called by muse, mutect2, varscan2
- SLC27A5 | c.1376G>A p.R459Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as rs762312130, COSV54019559; called by mutect2, varscan2
- SLC28A3 | c.1385C>A p.S462Y | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV66154131; called by muse, mutect2, varscan2
- SMC2 | c.2098G>A p.E700K | Missense Mutation (SNP) | VAF 98/210 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1340444872, COSV53961083; called by muse, mutect2, varscan2
- SNX13 | c.2749G>A p.E917K | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.798); catalogued as COSV68066598; called by muse, mutect2, varscan2
- SORCS1 | c.2953C>G p.P985A | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.546); catalogued as COSV53886472; called by muse, mutect2, varscan2
- SORL1 | c.5491C>G p.L1831V | Missense Mutation (SNP) | VAF 17/238 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as COSV52754337; called by muse, mutect2
- SPOP | c.79-1G>T p.X27_splice | Splice Site (SNP) | VAF 18/43 reads (42%) | catalogued as COSV100753651, COSV61654907; called by muse, mutect2, varscan2
- SPTAN1 | c.2386G>C p.E796Q | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63988498; called by muse, mutect2, varscan2
- STXBP3 | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV64182900; called by muse, mutect2, varscan2
- SYCP3 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV57149550; called by muse, mutect2, varscan2
- SYN3 | c.66G>A p.M22I | Missense Mutation (SNP) | VAF 89/113 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV60512296; called by muse, mutect2, varscan2
- SYNE2 | c.15771G>C p.K5257N | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV59959504; called by muse, mutect2
- TAS2R9 | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.381); catalogued as COSV53688760, COSV53689914; called by muse, mutect2, varscan2
- TATDN2 | c.517A>G p.R173G | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as rs1398929371, COSV55052953; called by muse, mutect2, varscan2
- TEKT1 | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs199498472, COSV58624074; called by muse, mutect2, varscan2
- TENM3 | c.5894G>A p.R1965K | Missense Mutation (SNP) | VAF 57/105 reads (54%) | SIFT tolerated (0.67); PolyPhen benign (0.206); catalogued as COSV69313990; called by muse, mutect2, varscan2
- TET2 | c.2302G>C p.D768H | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV54422528; called by muse, mutect2, varscan2
- THUMPD2 | c.1188-1G>C p.X396_splice | Splice Site (SNP) | VAF 17/39 reads (44%) | catalogued as COSV53188263; called by muse, mutect2, varscan2
- TIGD7 | c.1442G>A p.R481K | Missense Mutation (SNP) | VAF 79/94 reads (84%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV51916427; called by muse, mutect2, varscan2
- TLR4 | c.2365C>G p.L789V (on ENST00000355622 / NM_138554.5; = p.L749V on NM_003266.4) | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62923797; called by muse, mutect2, varscan2
- TNFSF10 | c.279G>C p.L93F | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.963); catalogued as COSV53842986; called by muse, mutect2, varscan2
- TOPBP1 | c.1742A>G p.K581R | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV53439045; called by muse, mutect2, varscan2
- TPR | c.1601C>T p.S534L | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV100824214, COSV66603174; called by muse, mutect2, varscan2
- TRANK1 | c.6910G>C p.E2304Q | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.368); catalogued as COSV57157309; called by muse, mutect2, varscan2
- TTLL6 | c.1750G>A p.A584T (on ENST00000393382 / NM_001130918.3; = p.A277T on NM_173623.3) | Missense Mutation (SNP) | VAF 270/634 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as COSV64978218; called by muse, mutect2, varscan2
- TTN | c.20764C>A p.H6922N (on ENST00000591111; = p.H5995N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/59 reads (29%) | PolyPhen benign (0); catalogued as COSV59887646, COSV60198311; called by muse, mutect2, varscan2
- TUBB4B | c.1134C>G p.F378L | Missense Mutation (SNP) | VAF 101/337 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV61116708, COSV61118083; called by muse, mutect2, varscan2
- UAP1L1 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV64306816; called by muse, mutect2, varscan2
- UBASH3B | c.1555G>C p.E519Q | Missense Mutation (SNP) | VAF 21/298 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV52498452; called by muse, mutect2
- UBR4 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.037); catalogued as COSV64394566; called by muse, mutect2, varscan2
- UBR5 | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 102/341 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55294047; called by muse, varscan2
- UBR5 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55294058; called by muse, varscan2
- UBR5 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as rs1164542118, COSV55294073; called by muse, mutect2, varscan2
- UBTF | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs1174382476, COSV57187382; called by muse, mutect2, varscan2
- UCP1 | c.222del p.Y75Tfs*39 | Frame Shift Del (DEL) | VAF 61/167 reads (37%) | catalogued as COSV53768201; called by mutect2, pindel, varscan2
- UHRF1 | c.1178C>G p.S393* (on ENST00000612630 / NM_001290050.1; = p.S406* on NM_013282.4) | Nonsense Mutation (SNP) | VAF 6/61 reads (10%) | catalogued as COSV53575738; called by muse, mutect2, varscan2
- UNC45A | c.679C>G p.Q227E | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.185); catalogued as COSV67816906; called by muse, mutect2, varscan2
- UPB1 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.835); catalogued as COSV58114742, COSV58115277; called by muse, mutect2, varscan2
- USP28 | c.2893G>A p.E965K | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.18); catalogued as COSV50164278; called by muse, mutect2, varscan2
- UTP18 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs376900305, COSV56584412; called by muse, mutect2, varscan2
- VCL | c.1174C>T p.Q392* | Nonsense Mutation (SNP) | VAF 44/54 reads (81%) | catalogued as COSV99280596; called by muse, mutect2, varscan2
- ZBTB34 | c.508C>G p.Q170E | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated (0.72); PolyPhen benign (0.011); catalogued as COSV59860370; called by muse, mutect2, varscan2
- ZBTB34 | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.515); catalogued as COSV59860380; called by muse, mutect2, varscan2
- ZCCHC3 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as COSV66643556; called by muse, mutect2, varscan2
- ZCCHC3 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.259); catalogued as COSV66643568; called by muse, mutect2, varscan2
- ZFYVE26 | c.2500G>C p.E834Q | Missense Mutation (SNP) | VAF 53/79 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61331191; called by muse, mutect2, varscan2
- ZNF221 | c.1321C>G p.Q441E | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV52110334, COSV52110351; called by muse, mutect2
- ZNF354A | c.206G>C p.G69A | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV59984069; called by muse, mutect2, varscan2
- ZNF667 | c.630T>A p.N210K | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV52637043; called by muse, mutect2, varscan2
- ZNF689 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.165); catalogued as COSV54909494; called by muse, mutect2, varscan2
- ZNF823 | c.463G>C p.E155Q (on ENST00000341191 / NM_001297610.2; = p.E111Q on NM_017507.2) | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.696); catalogued as COSV57874892; called by muse, mutect2, varscan2
- BAZ2A | c.2600_2601dup p.L868Cfs*38 | Frame Shift Ins (INS) | VAF 18/54 reads (33%) | called by mutect2, pindel, varscan2
- BCORL1 | c.2842C>T p.Q948* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | called by muse, mutect2, varscan2
- CDKN1A | c.237dup p.T80Hfs*9 | Frame Shift Ins (INS) | VAF 22/36 reads (61%) | called by mutect2, pindel, varscan2
- EHMT2 | c.1687C>G p.P563A | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.358); called by muse, mutect2
- EPRS1 | c.2138C>A p.S713* | Nonsense Mutation (SNP) | VAF 31/107 reads (29%) | called by muse, mutect2, varscan2
- FAT2 | c.5251G>T p.E1751* | Nonsense Mutation (SNP) | VAF 20/184 reads (11%) | called by muse, mutect2, varscan2
- KCNQ2 | c.2463C>G p.Y821* (on ENST00000359125 / NM_172107.4; = p.Y793* on NM_004518.6) | Nonsense Mutation (SNP) | VAF 19/34 reads (56%) | called by muse, mutect2, varscan2
- KCNV1 | c.885_888del p.S296Gfs*18 | Frame Shift Del (DEL) | VAF 23/74 reads (31%) | called by mutect2, pindel, varscan2
- OTUD6A | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by muse, mutect2
- PBX3 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2
- PCDHGB3 | c.502C>T p.Q168* | Nonsense Mutation (SNP) | VAF 14/298 reads (5%) | called by muse, mutect2
- TMEM126A | c.349_350dup p.P118Tfs*9 | Frame Shift Ins (INS) | VAF 79/290 reads (27%) | called by mutect2, pindel, varscan2
- TPTE | c.434T>C p.V145A (on ENST00000618007 / NM_199261.4; = p.V127A on NM_199259.4) | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.705); called by muse, mutect2
- TTF2 | c.2591C>G p.S864* | Nonsense Mutation (SNP) | VAF 45/130 reads (35%) | called by muse, varscan2
- AMIGO1 | c.1452G>A p.S484= | Silent (SNP) | VAF 21/313 reads (7%) | catalogued as rs543279248, COSV63990507; called by muse, mutect2
- ANXA10 | c.960T>C p.D320= | Silent (SNP) | VAF 41/94 reads (44%) | catalogued as COSV63739637; called by muse, mutect2, varscan2
- ASAP3 | c.792C>T p.L264= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV60876280; called by muse, mutect2, varscan2
- BCORL1 | c.2625C>G p.L875= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV54401260; called by muse, mutect2
- BRD3 | c.315C>T p.F105= | Silent (SNP) | VAF 5/67 reads (7%) | catalogued as COSV57705121; called by muse, mutect2
- CDH13 | c.1176C>T p.T392= | Silent (SNP) | VAF 51/57 reads (89%) | catalogued as COSV51846228; called by muse, mutect2, varscan2
- CHD5 | c.2469C>G p.L823= | Silent (SNP) | VAF 35/91 reads (38%) | catalogued as COSV52420240; called by muse, mutect2, varscan2
- CNGA2 | c.855C>A p.I285= | Silent (SNP) | VAF 133/160 reads (83%) | catalogued as COSV61705423; called by muse, mutect2, varscan2
- COPG1 | c.489C>T p.S163= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV100135888, COSV59115502; called by muse, mutect2, varscan2
- DAGLA | c.1797C>T p.L599= | Silent (SNP) | VAF 60/144 reads (42%) | catalogued as COSV57198047; called by muse, mutect2, varscan2
- DIDO1 | c.4509G>A p.Q1503= | Silent (SNP) | VAF 82/254 reads (32%) | catalogued as rs760003260, COSV56621202, COSV56628733; called by muse, mutect2, varscan2
- DZIP1 | c.1581A>G p.L527= (on ENST00000347108; = p.L508= on NM_014934.5) | Silent (SNP) | VAF 35/104 reads (34%) | catalogued as COSV61267674; called by muse, mutect2, varscan2
- EPB41L3 | c.69G>T p.A23= | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as rs763808085, COSV59450444; called by muse, mutect2, varscan2
- ESPL1 | c.2757C>G p.L919= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV57761057; called by muse, mutect2
- FCAR | c.657C>T p.I219= | Silent (SNP) | VAF 71/872 reads (8%) | catalogued as rs1322114552, COSV62030792; called by muse, mutect2
- GPR108 | c.1197G>A p.K399= (on ENST00000264080 / NM_001080452.1; = p.K157= on NM_020171.2) | Silent (SNP) | VAF 15/21 reads (71%) | catalogued as rs1464382293, COSV51185889, COSV99901444; called by muse, mutect2, varscan2
- GPR142 | c.1035G>A p.R345= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as rs1282526361, COSV100170943, COSV59519927; called by muse, mutect2, varscan2
- IGSF9 | c.3456C>T p.F1152= (on ENST00000368094 / NM_001135050.2; = p.F1136= on NM_020789.4) | Silent (SNP) | VAF 50/169 reads (30%) | catalogued as COSV57422875; called by muse, mutect2, varscan2
- INPP4B | c.1806G>C p.L602= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as COSV53735581; called by muse, mutect2, varscan2
- IRAK2 | c.612C>G p.V204= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as COSV56533673; called by muse, mutect2, varscan2
- ISL1 | c.564G>C p.L188= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV100045268, COSV57934701; called by muse, mutect2, varscan2
- ITIH4 | c.717C>T p.I239= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as COSV56576365; called by muse, mutect2
- KCNIP3 | c.654C>T p.F218= | Silent (SNP) | VAF 32/61 reads (52%) | catalogued as rs781346275, COSV54670978; called by muse, mutect2, varscan2
- KIAA0586 | c.3312T>G p.T1104= (on ENST00000619416 / NM_001244190.2; = p.T1043= on NM_014749.5) | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV54179187; called by muse, mutect2, varscan2
- LCE1D | c.219G>A p.L73= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV58271330; called by muse, mutect2, varscan2
- LCE1D | c.344G>A p.*115= | Silent (SNP) | VAF 50/55 reads (91%) | called by muse, mutect2, varscan2
- LIN52 | c.264T>C p.Y88= | Silent (SNP) | VAF 35/117 reads (30%) | catalogued as COSV73465940; called by muse, mutect2, varscan2
- MANEAL | c.1347C>T p.I449= (on ENST00000373045 / NM_001113482.1; = p.I227= on NM_152496.2) | Silent (SNP) | VAF 41/113 reads (36%) | catalogued as COSV100203949, COSV61116498; called by muse, mutect2, varscan2
- MPI | c.291C>T p.L97= | Silent (SNP) | VAF 19/149 reads (13%) | catalogued as COSV60397233; called by muse, mutect2, varscan2
- NEIL3 | c.1401G>A p.P467= | Silent (SNP) | VAF 42/102 reads (41%) | catalogued as rs1345930368, COSV52810541; called by muse, mutect2, varscan2
- NOSTRIN | c.168G>A p.L56= | Silent (SNP) | VAF 10/126 reads (8%) | catalogued as COSV58322866; called by muse, mutect2
- NSL1 | c.768G>A p.L256= | Silent (SNP) | VAF 27/224 reads (12%) | catalogued as COSV65329561; called by muse, mutect2, varscan2
- NUP210 | c.3393C>T p.L1131= | Silent (SNP) | VAF 89/216 reads (41%) | catalogued as rs750190590, COSV54409808; called by muse, mutect2, varscan2
- NUP85 | c.1970G>A p.*657= | Silent (SNP) | VAF 10/96 reads (10%) | called by muse, mutect2
- PBX2 | c.300C>T p.L100= | Silent (SNP) | VAF 27/32 reads (84%) | catalogued as COSV66709153; called by muse, mutect2, varscan2
- PHLDB1 | c.132C>T p.S44= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs528831163, COSV61880508; called by muse, mutect2, varscan2
- PKD2L1 | c.960G>A p.L320= | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as rs1267861830, COSV58397420; called by muse, mutect2
- PLA2R1 | c.2163C>G p.L721= | Silent (SNP) | VAF 4/77 reads (5%) | called by muse, mutect2
- PLEKHG4B | c.2577C>T p.H859= (on ENST00000283426; = p.H1215= on NM_052909.5) | Silent (SNP) | VAF 75/262 reads (29%) | catalogued as rs369268321; called by muse, mutect2, varscan2
- PLIN4 | c.2037G>C p.L679= (on ENST00000301286; = p.L694= on NM_001367868.2) | Silent (SNP) | VAF 15/314 reads (5%) | catalogued as rs1460327187, COSV56694653; called by muse, mutect2
- PPP4R1 | c.1146G>A p.T382= (on ENST00000400556 / NM_001042388.3; = p.T365= on NM_005134.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 181/269 reads (67%) | catalogued as rs200192249, COSV53283188; called by muse, mutect2, varscan2
- RAD51D | c.646C>T p.L216= | Silent (SNP) | VAF 57/138 reads (41%) | catalogued as COSV60005549; called by muse, mutect2, varscan2
- REV3L | c.1947C>T p.I649= | Silent (SNP) | VAF 25/28 reads (89%) | catalogued as COSV62621285; called by muse, mutect2, varscan2
- RFTN1 | c.207C>T p.L69= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV61921132; called by muse, mutect2, varscan2
- RUFY1 | c.153G>A p.R51= | Silent (SNP) | VAF 10/11 reads (91%) | catalogued as rs995180258, COSV60162067; called by muse, mutect2, varscan2
- SCN11A | c.309C>T p.F103= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as COSV56567423; called by muse, mutect2, varscan2
- SLC6A15 | c.1269C>G p.L423= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as COSV57026642, COSV57031255; called by muse, mutect2, varscan2
- SORCS2 | c.495G>C p.L165= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV61177344; called by muse, varscan2
- TMPRSS11E | c.939G>A p.V313= | Silent (SNP) | VAF 221/528 reads (42%) | catalogued as rs1208767776, COSV59520232; called by muse, mutect2, varscan2
- TPRG1L | c.585G>A p.P195= | Silent (SNP) | VAF 20/230 reads (9%) | catalogued as rs752528342, COSV54562209, COSV54562379; called by muse, mutect2
- TUBA1B | c.726G>A p.L242= | Silent (SNP) | VAF 8/168 reads (5%) | called by muse, mutect2
- UBASH3A | c.843G>A p.L281= | Silent (SNP) | VAF 12/271 reads (4%) | catalogued as rs1418294376, COSV52314403; called by muse, mutect2
- VRTN | c.1560G>C p.L520= | Silent (SNP) | VAF 49/174 reads (28%) | catalogued as COSV56442471; called by muse, mutect2, varscan2
- WDR90 | c.114G>A p.L38= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV53472664; called by muse, mutect2
- ZNF142 | c.2970G>A p.E990= (on ENST00000411696 / NM_001379660.1; = p.E790= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 11/251 reads (4%) | catalogued as COSV68744577; called by muse, mutect2
- ZNF84 | c.618C>G p.L206= | Silent (SNP) | VAF 36/87 reads (41%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501950 G>C | 5'Flank (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- AP000769.3 | chr11:65506286 G>C | 3'Flank (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- AP000769.5 | chr11:65498624 C>T | 5'Flank (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- CDRT15P3 | n.532G>C | RNA (SNP) | VAF 18/224 reads (8%) | catalogued as rs779206913; called by muse, mutect2
- EEF2 | c.613-118G>C | Intron (SNP) | VAF 17/33 reads (52%) | catalogued as COSV100500736, COSV100500821; called by muse, mutect2, varscan2
- EPDR1 | c.-23C>T | 5'UTR (SNP) | VAF 13/25 reads (52%) | catalogued as COSV52260837; called by muse, mutect2, varscan2
- FAM160A2 | c.1435+41G>A | Intron (SNP) | VAF 56/166 reads (34%) | catalogued as rs750055025, COSV56410535, COSV99791881; called by muse, mutect2, varscan2
- GLRXP3 | n.139G>A | RNA (SNP) | VAF 114/138 reads (83%) | catalogued as rs779143791; called by muse, mutect2, varscan2
- IKBIP | c.297+7725G>A | Intron (SNP) | VAF 58/128 reads (45%) | catalogued as COSV54490550; called by muse, mutect2, varscan2
- NDUFA3 | c.*108C>G | 3'UTR (SNP) | VAF 5/79 reads (6%) | catalogued as COSV57838032; called by muse, mutect2
- PPHLN1 | c.1024+23C>T | Intron (SNP) | VAF 45/97 reads (46%) | catalogued as COSV56734056; called by muse, mutect2, varscan2
- RMDN2 | c.452+20858G>A | Intron (SNP) | VAF 148/166 reads (89%) | catalogued as rs1357489721, COSV52227393; called by muse, mutect2, varscan2
- TTN | c.10360+4987C>G | Intron (SNP) | VAF 23/54 reads (43%) | catalogued as COSV60198318; called by muse, mutect2, varscan2
